Surgical pathology report (de-identified scan), TCGA case TCGA-A3-A6NJ, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-A6NJ-01A (Primary Tumor).

[page 1 of 2]
Surg Path Final Report

* Final Report *

Result Type: Surg Path Final Report
Result Date:
Result Status:
Result Title: Surgical Pathology Final Report
Verified By:
Encounter info:

ICD-O-3
Carcinoma, renal cell
Clear cell 8312/3
Site @ Kidney NOS
C64.9
9/5 7/22/13

* Final Report *

Final Diagnosis (Verified)

Left kidney, nephrectomy:

Clear cell renal cell carcinoma.

Fuhrman nuclear grade 1/4.

Tumor dimension: 5.7 cm, located in the lower pole of the kidney, confined to the kidney with no evidence of lymphovascular invasion.

Separate focus of clear cell renal cell carcinoma, Fuhrman nuclear grade 1/4, 0.4 cm in greatest dimension, superior to larger mass.

Sarcomatoid features: Not identified.

Tumor necrosis: Not identified.

Ureteral and vascular margins are free of involvement.

Adjacent adrenal gland free of involvement.

AJCC pathologic stage: pT1a.pNX.

Signature Line

Performing Lab (Verified)

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
Surg Path Final Report

* Final Report *

Gross Description (Verified)

"A, Left kidney." Received is a 289 gram, 12.5 x 6.2 x 5.8 cm kidney with a scant amount of attached perinephric fat. The kidney has been previously bivalved. There is a 1.5 cm segment of ureter attached to the kidney. There is a 5.7 x 5.2 cm golden-yellow, cystic mass in the lower pole of the kidney. The mass is edematous. The mass grossly appears to abut the renal capsule. There is a scant amount of perinephric fat attached to the kidney adjacent to the mass. The Gerota's fascia and renal capsule overlying the mass will be inked black. Identified in the remaining renal parenchyma is a 0.4 x 0.3 cm golden-yellow nodule. This nodule is 3.7 cm superior to the previously described mass. The nodule grossly appears to abut the renal capsule. The Gerota's fascia overlying this nodule will be inked orange. Also identified in the remaining renal parenchyma is a 1.4 cm cortical cyst. The internal aspect of the cyst is smooth with no excrescence. The uninvolved renal parenchyma is red-brown. The hilum of the kidney is examined, and no lymphoid tissue is grossly identified. Attached to the kidney is a 3.7 x 1.4 x 0.6 cm portion of adrenal gland. No masses or lesions are grossly identified in the renal gland. "A1," ureteral and vascular margins; "A2-A3," mass with adjacent renal capsule and Gerota's fascia; "A4-A5," random sections mass; "A6," nodule in remaining renal parenchyma; "A7," cortical cyst; "A8," random sections uninvolved renal parenchyma; "A9," random sections adrenal gland.

Signature Line

Clinical Information (Verified)

Renal mass.

Completed Action List:

Printed by:
Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file fa3f945b-abb2-4c3f-b133-264db5d5de77 (TCGA-A3-A6NJ.BBABA189-DC47-4740-8CBC-AC567759AF1C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).